Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2GZ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2GZ-01A (Primary Tumor).

ICD-0-3
Carcinoma, squamous cell, NOS 8070/3
Site: Cervix, NOS C53.9
6/14/11

PAGE:1

PATIENT:
AGE/SEX: /F DOB: SUBM DR:
ACCT #: LOC:
CLIENT PATIENT ID:

SPEC #: Status: Obtained: -UNK Received:

CLINICAL HISTORY:

SPECIMEN/PROCEDURE:

1. CERVIX - BIOPSY

IMPRESSION:

CERVIX, 1 O'CLOCK, BIOPSY:

- Mainly degenerative tissue.
- Minute fragments of viable dysplastic squamous cells, consistent with invasive squamous cell carcinoma.

Dictated
Entered:

GROSS DESCRIPTION:

Received, labeled with the patient's name and "Succeed", are two pale pink to red-tan tissue fragments ranging from 0.4 - 1.1 cm in greatest dimension, entirely submitted in one cassette.

Dictated
Entered:

CPT Codes:

CERVICAL BIOPSY (1)/88305/3997100

ICD9 Codes:

180.9

Electronically Signed by:

** END OF REPORT **

Source: NCI Genomic Data Commons file 4d96dcda-42a8-41bb-ac8f-cba48d36869b (TCGA-EK-A2GZ.793DCC7F-E9F9-4A23-A5C3-2738AD4E0091.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).